Surgical pathology report (de-identified scan), TCGA case TCGA-DQ-7594, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Of Michigan, specimen TCGA-DQ-7594-01A (Primary Tumor).

Reg# [REDACTED] Name: [REDACTED] DOB: [REDACTED] Sex: [REDACTED] Age: [REDACTED] User Name: [REDACTED]

ACCN Number	Order Test Code	Order Test Name	Last Updated
ACCN: [REDACTED] Collected: [REDACTED]	SPF	SP FINAL REPORT	Updated [REDACTED]
SP FINAL REPORT		Source:	

HISTORY:

History of case: Positive biopsy, squamous cell carcinoma, moderately-differentiated, and positive for p16 of right tongue. Operative Procedure/Tissue Submitted: DL, BX.

GROSS:

1. "Right base of tongue" Received in formalin in a small container is a 1.2 x 0.5 x 0.2 cm mucosal strip, with granular surface. Submitted intact. (1ns)
2. "Right, level 2 lymph node" Received in formalin in a small container is a 1.1 x 0.2 x 0.1 cm red-tan soft tissue fragment. Submitted intact. (1ns)

MICROSCOPIC DIAGNOSIS:

1. Right base of tongue, biopsy: Invasive, predominantly nonkeratinizing poorly differentiated squamous cell carcinoma. Tumor invades to a depth of 0.5 cm. Immunohistochemical stain for p16 positive.
2. Soft tissue of right neck, level II, excision: Skeletal muscle with scar, acute and chronic inflammation, and foreign body giant cell reaction. Negative for neoplasm, deeper levels and cytokeratin immunohistochemical stain confirmatory.

I, [REDACTED] the signing staff pathologist, have personally examined and interpreted the slides from this case.

(electronic signature)

Close

Source: NCI Genomic Data Commons file 6c6eb1c0-81ac-43c5-b0c8-2a008b37a714 (TCGA-DQ-7594.6DE18C19-0C3D-4563-B2EE-8F248F31E068.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).